Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A146, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A146-01A (Primary Tumor).

ICIS 10-3
Infiltrating duct carcinoma, NOS
3506/3 bx in/2x/10
Site: breast, NOS 250.9

page 1 / 1

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Examination No.:

Patient: [REDACTED] PESEL: Age: Gender: F

Material: Multiple organ resection - right breast

Unit in charge:

Physician in charge:

Material collected on: Material received on:

Expected time of examination: up to

Clinical diagnosis:

Examination performed on:

✓ Macroscopic description:

Right breast, sized 25.3 x 18.2 x 5.3 cm, removed along with axillary tissues sized 5 x 7 x 3 cm and a skin flap of 24.7 x 11.6 cm. Weight 1,100 g.

Tumour sized 3.2 x 1 x 1.4 cm in the upper outer quadrant, placed 3 cm from the upper edge, 0.8 cm from the base and 1.9 cm from the skin.

Microscopic description:

Carcinoma ductale invasivum - NHG1 (2 + 2+1:2 mitoses/ 10 HPF, visual area diameter 0.55 mm). Numerous focuses of carcinoma ductale in situ (DCIS) found within tumour (solid and cribrate type, with medium nuclear atypia, comedo necrosis and calcifications, 15% of the tumour). Mamilla sine laesionibus. Glandular tissue showing lesions of the type mastopathia fibrosa.

AXILLARY LYMPH NODES:

Lymphonodulitis chronica et sinus histiocytosis lymphonodorum (No XI).

✓ Examination result:

Carcinoma ductale invasivum et ductale in situ mammae dextrae.
(NHG1, pT2, pN0).

INVASIVE AND IN SITU DUCTAL CARCINOMA OF THE RIGHT BREAST

Compliance validated by:

Examination performed on

Results of immunohistochemical examination:

Estrogen receptors found in 75% of neoplastic cell nuclei. Progesterone receptors found in 75% of neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO.

Negative reaction in invasive carcinoma cells (Score = 1+)

Compliance validated by:

Local Malignancy History		
Just Synchronous Primary Noted		

Source: NCI Genomic Data Commons file a2ab247f-228a-429f-b70b-27fc74f70273 (TCGA-D8-A146.79749F5D-329A-400D-8511-C4CF479C1FCC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).